Surgical pathology report (de-identified scan), TCGA case TCGA-MQ-A4LJ, project TCGA-MESO (Mesothelioma), tissue source site Washington University - NYU, specimen TCGA-MQ-A4LJ-01A (Primary Tumor).

[page 1 of 4]
Result type: Report
Result date:
Result status:
Result title:

SPECIMEN DESCRIPTION

* Final Report *

SPECIMEN DESCRIPTION

(NOTE)
SUBCUTANEOUS NODULE
CHEST TUBE SCAR
THORACOTOMY SCAR
SUBCUTANEOUS NODULE
PLEURA
FISSURE
PERICARDIAL NODULE
PHRENIC NERVE
SUBAORTIC LYMPH NODE
AORTIC LYMPH NODE
LEVEL 7
LEVEL 9
DIAPHRAMATIC SULCUS

1CD-0-3
mesothelioma, epithelioid, NOS 9152/3
Site: pleura, NOS C38.4

lw
10/4/12

SURGICAL PATHOLOGY REPORT

LOCATION:

PATHOLOGY NO.:

HOSPITAL NO.:
ACCOUNT NO.:
DATE RECEIVED:
DATE REPORTED:

PATIENT'S NAME:
AGE/SEX/DOB:
PHYSICIAN(S):
COPY TO:

M

DIAGNOSIS:

A. CLINICALLY FROM "SUBCUTANEOUS NODULE":
FIBROCONNECTIVE TISSUE AND SKELETAL MUSCLE WITH REACTIVE CHANGES AT THE
PREVIOUS OPERATION SITE INCLUDING SUTURE GRANULOMAS AND FIBROSIS.
NO TUMOR IS SEEN.

B. CLINICALLY FROM "CHEST TUBE SCAR":
SKIN AND SUBCUTANEOUS TISSUE WITH REACTIVE CHANGES INCLUDING FIBROSIS, FAT
NECROSIS AND GRANULATION TISSUE FORMATION.
NO TUMOR IS SEEN.

C. CLINICALLY FROM "THORACOTOMY SCAR":
SKIN AND SUBCUTANEOUS TISSUE WITH REACTIVE CHANGES INCLUDING FIBROSIS, FAT
NECROSIS AND GRANULATION TISSUE TYPE REACTION.
NO TUMOR IS SEEN.

Printed by:
Printed on:

Page 1 of 4
(Continued)

[page 2 of 4]
[REDACTED]

D. CLINICALLY FROM "SUBCUTANEOUS NODULE":
ADIPOSE TISSUE WITH MILD REACTIVE CHANGES.
NO TUMOR IS SEEN.

E. PLEURA; PLEURECTOMY:
MALIGNANT MESOTHELIOMA, EPITHELIOID WITH TUBULOPAPILLARY PATTERN AND PROMINENT
GLAND FORMATION.

F. CLINICALLY FROM "FISSURE", BIOPSY:
MALIGNANT MESOTHELIOMA WITH PROMINENT TUBULOPAPILLARY PATTERN, ASSOCIATED WITH
MILD ACUTE AND CHRONIC INFLAMMATION.

G. CLINICALLY FROM "PERICARDIAL TISSUE", BIOPSY:
MALIGNANT MESOTHELIOMA WITH PROMINENT GLANDULAR FORMATION INVOLVING
FIBROADIPOSE TISSUE.

H. NERVE, PHRENIC; EXCISION:
SEGMENT OF NERVE AND SURROUNDING FIBROCONNECTIVE TISSUE WITH NO SIGNIFICANT
HISTOLOGIC ALTERATION.
NO TUMOR IS SEEN.

I. LYMPH NODE, SUBAORTIC, EXCISION:
ONE NEGATIVE LYMPH NODE (0/1):

J. LYMPH NODE, AORTIC, EXCISION:
METASTATIC MALIGNANT MESOTHELIOMA, A MINUTE FOCUS OF, INVOLVING THE SINUSES OF
ONE OF TWO LYMPH NODES (1/2, MICROSCOPIC).

K. LYMPH NODES, LEVEL 7, EXCISION:
FIVE NEGATIVE LYMPH NODES (0/5).

L. LYMPH NODES, LEVEL 9, EXCISION:
METASTATIC MALIGNANT MESOTHELIOMA INVOLVING THREE OF THREE LYMPH NODES (3/3).
THE TUMOR INVOLVES PERINODAL VESSELS.

M. CLINICALLY FROM "DIAPHRAGMATIC SULCUS":
MALIGNANT MESOTHELIOMA, EPITHELIOID TYPE WITH TUBULOPAPILLARY FEATURES.

=====

SPECIMEN: A SUBCUTANEOUS NODULE
B CHEST TUBE SCAR
C THORACOTOMY SCAR
D SUBCUTANEOUS NODULE
E PLEURA
F FISSURE
G PERICARDIAL NODULE
H PHRENIC NERVE

Printed by:
Printed on:

Page 2 of 4
(Continued)

[page 3 of 4]
I SUBAORTIC LYMPH NODE
J AORTIC LYMPH NODE
K LEVEL 7
L LEVEL 9
M DIAPHRAGMATIC SULCUS

OPERATION: L PNEUMONECTOMY

PRE-OP DIAGNOSIS: MESOTHELIOMA

POST-OP DIAGNOSIS: SAME

CLINICAL DATA: NOT GIVEN

GROSS DESCRIPTION: Received fresh for frozen section labeled subcutaneous nodules is one fragment of fibroadipose tissue measuring 1.5 x 1 x 0.3 cm. Entirely submitted for frozen section in one block.

FROZEN SECTION DIAGNOSIS: FIBROSIS AND REACTIVE INFLAMMATORY CHANGES WITH FOREIGN BODY TYPE GIANT CELLS. NO EVIDENCE OF MESOTHELIOMA.

REPORTED TO THE O. R. BY DR.

B. Received fresh labeled chest tube scar is an ellipse of white wrinkled skin measuring 5 x 2 and extending to a depth of 1.5 cm. A 1.7 old scar is present and a 2 cm incision is also present in the skin. The specimen is inked and serially sectioned. Representative sections are submitted in two cassettes.

C. Received fresh labeled thoracotomy scar is an ellipse of white-pink skin measuring 11 x 2 cm and extending to a depth of 2 cm, 5 cm old scar is present on the skin surface. The specimen is inked and serially sectioned. Representative sections are submitted in one cassette.

D. Received fresh labeled subcutaneous nodule is one fragment of adipose tissue measuring 5 x 3.5 x 1 cm. This is inked and serially sectioned. The cut surface is homogeneous, lobulated and adipose. Representative sections are submitted in one cassette.

E. Received fresh labeled pleural is one fragment of fibroadipose tissue measuring 35 x 20 x 1.5 cm. The specimen is serially sectioned and the cut surface is diffusely white, indurated with a thickness varying from 0.7 x 1.5 cm. It is also multinodular, showing multiple white-tan, indurated nodules. A hemorrhagic and fibropurulent exudate is present focally. Sections for EM and frozen tissue bank are taken. Representative sections are submitted in 12 cassettes. There is also, in the same container, multiple fragments of pink-tan granular and membranous tissue aggregating to 6 x 2 x 0.5 cm. Representative sections are submitted in cassettes 13, 14 and 15.

F. Received fresh labeled fissure are two membranous fragments of pink-tan

Printed by:
Printed on:

Page 3 of 4
(Continued)

[page 4 of 4]
[REDACTED]

granular and rubbery tissue measuring 2.5 x 2.5 x 0.2 cm and 2 x 1 x 0.2 cm. Representative sections are submitted in one cassette.

G. Received fresh labeled pericardial nodule is one fragment of fibroadipose tissue measuring 3 x 2 x 0.3 cm. An 0.5 x 0.5 area of fibrosis is identified. Representative sections are submitted in one cassette.

H. Received fresh labeled phrenic nerve is one nerve measuring 15 cm in length and 0.5 cm in diameter, stapled at one end, grossly unremarkable. This is serially sectioned and representative section is submitted in one cassette.

I. Received fresh labeled subaortic lymph node is one anthracotic lymph node measuring 3 x 1.5 cm entirely submitted in one cassette.

J. Received fresh labeled aortic lymph node is one fragment of fibroadipose tissue measuring 5 x 2.5 x 1 cm. Two lymph nodes are identified, measuring from 0.5 to 1 cm. Grossly unremarkable and submitted as follows:
1-three possible lymph nodes,
2-one lymph node bisected.

K. Received fresh labeled level 7 are multiple fragments of dark brown and pink tissue aggregating to 2.5 x 1.5 x 0.5 cm. Entirely submitted in two cassettes.

L. Received fresh labeled level 9 are three lymph nodes measuring from 0.5 to 2 cm. One lymph node measuring 1.2 cm is entirely replaced by tumor. The lymph nodes are submitted as follows:
1-two possible lymph nodes,
2-one lymph node bisected.

M. Received fresh labeled diaphragmatic sulcus are multiple segments of multinodular pink-tan indurated tissue aggregating to 10 x 5 x 1 cm. The cut surface is white and indurated. Representative sections are submitted in two cassettes.

PATHOLOGIST: _____

Completed Action List:

Printed by:
Printed on:

Page 4 of 4
(End of Report)

10/4/12

Source: NCI Genomic Data Commons file 834b91e4-a3da-4627-9fe7-dfe848db9367 (TCGA-MQ-A4LJ.19CD856A-FF63-412E-BB66-E49415C63D94.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).